CGCI case HTMCP-01-17-00567 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/935abe5f-066d-4e3f-ac0d-59861c3ddf2c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 527 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 69.7 years (25,444 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 504 days (1.4 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Liver; Sites of involvement: Liver / Lung, NOS.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Lymph node involved site: Splenic.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Iliac, NOS; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 4.6 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for progressive disease; adjuvant Radiation Therapy, NOS; Surgery, NOS, for progressive disease.

Follow-up (7 entries)
- Days to follow up: 0 days; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 308 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 308 days.
- Days to follow up: 308 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 308 days.
- Days to follow up: 308 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 308 days.
- Days to follow up: 504 days (1.4 years); Disease response: With Tumor.
- Progression or recurrence: Yes.
- Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD3 (IHC): Negative.
- CD30 (IHC): Positive.
- CD5 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- PAX5 (IHC): Positive.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Test (IHC): Negative; Specialized molecular test: EBER.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 69.3 kg; Height: 167.6 cm; BMI: 24.7; CD4 count: 132; Haart treatment indicator: Yes; HIV viral load: 64.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 10; Tobacco smoking quit year: 2019.

Biospecimens (2 samples)
- Sample HTMCP-01-17-00567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-17-00567-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Tobacco smoking history indicator: 4; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- History of disease: Year of HIV diagnosis: 2008; Haart therapy at diagnosis: Yes; Cdc HIV risk group: IV drug user.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lung.
- Primary pathology: Extranodal site involvement: 2; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator); Pos lymph node location: Other Location, specify.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: P53 >20%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: PAX5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 11: Immunophenotypic analysis tested: Eber; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed: Ebv status malignan cells method: EBER in situ hybridization.
- New tumor event 1: New tumor event type: Distant Metastasis; New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- New tumor event 3: New tumor event type: Distant Metastasis; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00567-01A-01E-14903:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00567-01A-01S-14903:
- % tumour top: 90
- % tumour bottom: 90
